Somatic mutation profile of tumor specimen TCGA-CC-A3M9-01A (aliquot TCGA-CC-A3M9-01A-11D-A20W-10) from TCGA case TCGA-CC-A3M9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, spindle cell variant; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 45.1 years (16,460 days).
Specimen TCGA-CC-A3M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ffa430a-fa46-44d9-ba1c-29e6a72407f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A3M9-10A (Blood Derived Normal), aliquot TCGA-CC-A3M9-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fdc771f-e9c3-482a-b6be-b0613a9918b4

The open-access MAF lists 144 somatic variants for this specimen: 103 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 38, Nonsense Mutation 5, Frame Shift Ins 3, Intron 1, Frame Shift Del 1, In Frame Ins 1, 5'UTR 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 94/184 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV58444117; called by muse, mutect2
- ARHGAP26 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV50830827; called by muse, mutect2, varscan2
- ATP6V0D2 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53414967, COSV53415362; called by muse, mutect2, varscan2
- BRF1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV59269452; called by muse, mutect2, varscan2
- C11orf87 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV59356112, COSV59357138; called by muse, mutect2, varscan2
- CDH11 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339416150, COSV51752888, COSV51764246; called by muse, mutect2, varscan2
- CEP170 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1484422123, COSV60509828; called by muse, mutect2, varscan2
- CEP192 | c.2429A>T p.D810V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58065263; called by muse, mutect2, varscan2
- CFTR | c.2747T>A p.F916Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV50058674; called by muse, mutect2, varscan2
- CHRNB2 | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63808429; called by muse, mutect2, varscan2
- CHRNB3 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 161/403 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51495365; called by muse, mutect2, varscan2
- CNGB3 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60690913; called by muse, mutect2, varscan2
- CNN3 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54730664; called by muse, mutect2, varscan2
- COL16A1 | c.1022A>T p.E341V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV54707241; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>A p.R1123S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.953); catalogued as COSV51958062, COSV51959307; called by muse, mutect2, varscan2
- CTTNBP2 | c.804A>C p.Q268H | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50407482; called by muse, varscan2
- CTTNBP2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775961843, COSV50392601, COSV99353371; called by muse, varscan2
- DAB2IP | c.2480C>G p.S827C (on ENST00000408936; = p.S799C on NM_032552.3) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52260957; called by muse, mutect2, varscan2
- DCC | c.3998C>T p.T1333I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV71433241; called by muse, mutect2, varscan2
- DDR2 | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV63371535; called by muse, mutect2, varscan2
- DIAPH3 | c.2750C>T p.T917M (on ENST00000400324 / NM_001042517.2; = p.T654M on NM_030932.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs372502709; called by muse, mutect2
- DNAAF3 | c.1556A>G p.E519G (on ENST00000524407 / NM_001256715.2; = p.E566G on NM_178837.4) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV61277447; called by muse, mutect2, varscan2
- EPB41L4A | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54871268; called by muse, mutect2, varscan2
- ERCC1 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV50004366; called by muse, mutect2, varscan2
- ERO1B | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100524119; called by muse, mutect2
- EXO5 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV56415834; called by muse, mutect2, varscan2
- EXOC3 | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1281960589, COSV59267028; called by muse, mutect2
- FNDC7 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV54754525; called by muse, mutect2, varscan2
- FOXRED2 | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53400227; called by muse, mutect2, varscan2
- FPR1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as COSV59052373; called by muse, mutect2, varscan2
- GALNT6 | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100695555; called by muse, mutect2
- GALR1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV55317392; called by muse, mutect2
- GOLGA3 | c.1032G>T p.M344I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV52633240; called by muse, mutect2, varscan2
- GPATCH8 | c.4417G>T p.A1473S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV59195268; called by muse, mutect2, varscan2
- GPR158 | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66271932; called by muse, mutect2, varscan2
- GRAMD2B | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs936842199, COSV53506728, COSV53509950; called by muse, mutect2, varscan2
- GRM4 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 49/148 reads (33%) | catalogued as COSV65214275; called by muse, mutect2, varscan2
- HSPA4 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV59182591; called by muse, mutect2, varscan2
- IWS1 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 37/251 reads (15%) | catalogued as rs757568675, COSV54869021; called by muse, mutect2, varscan2
- IZUMO1R | c.388G>A p.E130K (on ENST00000440961; = p.E137K on NM_001199206.3) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV60622817; called by muse, mutect2, varscan2
- KCNA7 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55503596, COSV55504546; called by muse, mutect2, varscan2
- KDR | c.3957C>A p.Y1319* | Nonsense Mutation (SNP) | VAF 48/151 reads (32%) | catalogued as COSV55766843; called by muse, mutect2, varscan2
- KIAA1328 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54455329; called by muse, mutect2, varscan2
- KIF11 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV53271107; called by muse, mutect2, varscan2
- KIF26A | c.3533G>T p.G1178V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV59467146; called by muse, mutect2, varscan2
- LAMA1 | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.502); catalogued as COSV67538330; called by muse, mutect2
- LAMTOR3 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV56952303; called by muse, mutect2, varscan2
- LHX5 | c.1140C>A p.S380R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV55663014; called by muse, mutect2, varscan2
- LRRC71 | c.1402A>G p.M468V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV59354984; called by muse, mutect2
- MAGEC2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1256910607, COSV55999624; called by muse, mutect2, varscan2
- MAP1B | c.2293T>C p.S765P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57100330; called by muse, mutect2, varscan2
- MAP7D3 | c.1027G>C p.V343L | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV60171170, COSV60171596; called by muse, mutect2, varscan2
- MAPK9 | c.620A>C p.D207A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58122620; called by muse, mutect2, varscan2
- MRGPRX1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs1309719773, COSV57107643; called by muse, mutect2, varscan2
- MTFR2 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63079321; called by muse, mutect2
- MYO1B | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58431926; called by muse, mutect2, varscan2
- MYO3B | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58705130, COSV58711200; called by muse, mutect2, varscan2
- NDC80 | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1027813739, COSV55248319; called by muse, mutect2, varscan2
- NOS3 | c.2984G>C p.G995A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.304); catalogued as COSV52490684; called by muse, mutect2, varscan2
- NRXN3 | c.2060G>A p.S687N (on ENST00000335750 / NM_001330195.2; = p.S314N on NM_004796.6) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV59757502, COSV59781596; called by muse, mutect2, varscan2
- NUP210 | c.3158A>T p.Q1053L | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54407360; called by muse, mutect2, varscan2
- OR3A3 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99351432; called by muse, mutect2
- PARD3 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV60751555; called by muse, mutect2, varscan2
- PCDH11Y | c.782G>C p.R261T (on ENST00000400457 / NM_032973.2; = p.R250T on NM_032971.3) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV53082491, COSV53093549; called by muse, mutect2, varscan2
- PCDH19 | c.3182C>A p.A1061E (on ENST00000373034 / NM_001184880.2; = p.A1013E on NM_020766.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs756173536, COSV55259586, COSV55266917; called by muse, mutect2, varscan2
- PCDH9 | c.3334A>G p.N1112D (on ENST00000377865 / NM_203487.3; = p.N1078D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.122); catalogued as COSV100121973; called by muse, mutect2
- PDCD6 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53778057; called by muse, mutect2, varscan2
- PHF20 | c.2039G>T p.C680F | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100926465, COSV64976088; called by muse, mutect2, varscan2
- POLQ | c.6985G>T p.A2329S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51753452; called by muse, mutect2, varscan2
- PSMC4 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50095650; called by muse, mutect2, varscan2
- PTPRH | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs748917262, COSV54746168; called by muse, mutect2, varscan2
- RBM14 | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59559165; called by muse, mutect2, varscan2
- SEMA6B | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs755696579, COSV56704146; called by muse, mutect2, varscan2
- SLC12A1 | c.111T>A p.D37E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV57709933; called by muse, mutect2, varscan2
- SLC16A6 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs139961659; called by muse, mutect2, varscan2
- SLC6A20 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62071462; called by muse, mutect2, varscan2
- SORCS1 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53871885; called by muse, mutect2
- SSTR3 | c.1121T>A p.V374D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60729564, COSV60730253; called by muse, mutect2, varscan2
- SYT8 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV53289932; called by muse, mutect2, varscan2
- TGIF2LX | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV99383256; called by muse, mutect2, varscan2
- TMC6 | c.2091G>T p.W697C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV59809389; called by muse, mutect2, varscan2
- TMEM185A | c.39-1G>T p.X13_splice | Splice Site (SNP) | VAF 30/53 reads (57%) | catalogued as rs376945268, COSV57559654; called by muse, mutect2, varscan2
- TNNT3 | c.476C>T p.S159F (on ENST00000397301 / NM_001367846.1; = p.S148F on NM_006757.4) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53487174; called by muse, mutect2, varscan2
- TRIM24 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.968); catalogued as rs201288398, COSV58973080; called by muse, mutect2, varscan2
- U2AF1L4 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV53075183; called by muse, mutect2, varscan2
- UBE2Q2 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1465051873, COSV51193325; called by muse, mutect2, varscan2
- UNC13C | c.941A>G p.H314R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.084); catalogued as COSV52880733; called by muse, varscan2
- VPS26C | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55706415; called by muse, mutect2, varscan2
- WDR49 | c.611A>T p.E204V (on ENST00000308378 / NM_001366158.1; = p.E545V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV57709397; called by muse, mutect2, varscan2
- WWP2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV63125427; called by muse, mutect2, varscan2
- XIRP2 | c.1065C>G p.N355K (on ENST00000628543; = p.N530K on NM_152381.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs112137897, COSV54705287; called by mutect2, varscan2
- ZNF496 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 45/140 reads (32%) | catalogued as COSV54173051, COSV54178006; called by muse, mutect2, varscan2
- ZNF585B | c.2171G>C p.G724A | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57215853; called by muse, mutect2, varscan2
- ZNF675 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs200866824, COSV63096268; called by muse, mutect2, varscan2
- ZNF709 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67194872; called by muse, mutect2, varscan2
- ZNF878 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.723); catalogued as rs767645991, COSV72156026; called by muse, mutect2, varscan2
- GDF2 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPD | c.782_783insG p.Q262Tfs*11 | Frame Shift Ins (INS) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- TET2 | c.66_68dup p.P23dup | In Frame Ins (INS) | VAF 9/37 reads (24%) | called by pindel, varscan2
- TET2 | c.69_70insCA p.I24Qfs*26 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by muse*, mutect2, varscan2*
- TRIM4 | c.1118dup p.N373Kfs*13 | Frame Shift Ins (INS) | VAF 15/124 reads (12%) | called by mutect2, pindel, varscan2
- UBA6 | c.1329_1332del p.Y443* | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- ACAN | c.7557C>A p.V2519= (on ENST00000560601 / NM_001369268.1; = p.V2481= on NM_013227.3) | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV61361868; called by muse, mutect2, varscan2
- CNTNAP5 | c.3093A>T p.T1031= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as COSV70489280; called by muse, mutect2, varscan2
- CRISPLD1 | c.1155A>G p.T385= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as rs1289046923, COSV51548920; called by muse, mutect2, varscan2
- CSMD1 | c.1182A>G p.T394= (on ENST00000520002; = p.T393= on NM_033225.6) | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs770764898, COSV101212601, COSV68212125; called by muse, mutect2, varscan2
- CSMD2 | c.306A>C p.P102= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV53918846; called by muse, mutect2, varscan2
- DCLRE1B | c.1296A>G p.S432= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs748972641, COSV65812917; called by muse, mutect2, varscan2
- FOXL1 | c.60G>C p.L20= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV57214479, COSV57214613; called by muse, mutect2, varscan2
- HNRNPCL1 | c.732A>G p.A244= | Silent (SNP) | VAF 15/189 reads (8%) | catalogued as COSV58612079; called by muse, mutect2
- KIF22 | c.1068C>T p.V356= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV50715349; called by muse, mutect2, varscan2
- KLC3 | c.1311G>A p.E437= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as COSV67268484; called by muse, mutect2, varscan2
- LMTK2 | c.3204T>C p.P1068= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV51997056; called by muse, mutect2
- LRRC74A | c.705G>A p.G235= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs374431496; called by muse, mutect2, varscan2
- LYPD3 | c.48A>T p.A16= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV54988600; called by muse, mutect2, varscan2
- MEGF6 | c.1512G>A p.T504= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs771007651, COSV53887509; called by muse, mutect2, varscan2
- MFSD4A | c.1392T>C p.Y464= | Silent (SNP) | VAF 65/293 reads (22%) | catalogued as COSV65656545; called by muse, mutect2, varscan2
- MGLL | c.615G>A p.L205= (on ENST00000398104 / NM_001003794.2; = p.L215= on NM_007283.6) | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV54026056; called by muse, mutect2, varscan2
- MMAA | c.909A>G p.Q303= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV55580344; called by muse, mutect2
- MUC16 | c.38772T>C p.D12924= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as COSV67471163; called by muse, mutect2
- MYH2 | c.3051G>A p.Q1017= | Silent (SNP) | VAF 144/305 reads (47%) | catalogued as COSV55439788; called by muse, mutect2, varscan2
- OSBPL7 | c.2334C>T p.A778= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as COSV50109441; called by muse, mutect2, varscan2
- PCDH15 | c.5157T>A p.A1719= | Silent (SNP) | VAF 48/197 reads (24%) | catalogued as COSV64699687; called by muse, mutect2, varscan2
- PCDHGB7 | c.807G>A p.Q269= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53962107, COSV54012747; called by muse, mutect2
- PDCD1LG2 | c.492C>A p.T164= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV67204763; called by muse, mutect2, varscan2
- PMP2 | c.192C>G p.S64= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV56267185, COSV56267230; called by muse, mutect2, varscan2
- PRSS35 | c.381C>A p.T127= | Silent (SNP) | VAF 10/155 reads (6%) | catalogued as COSV63800439, COSV63800694; called by muse, mutect2
- SCN11A | c.222A>T p.I74= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV56571571; called by muse, mutect2, varscan2
- SCN5A | c.1551G>A p.R517= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV61126829; called by muse, mutect2, varscan2
- SHC4 | c.1323G>A p.G441= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as COSV60109144, COSV60113015; called by muse, mutect2, varscan2
- SLC13A4 | c.1137T>C p.T379= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV62461327; called by muse, mutect2, varscan2
- STK33 | c.108A>G p.P36= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV59402577; called by muse, mutect2, varscan2
- TMEM260 | c.999A>G p.S333= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs769725447, COSV55099999; called by muse, mutect2, varscan2
- UBE3A | c.1074T>C p.S358= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV51664731, COSV51665809; called by muse, mutect2, varscan2
- UCHL3 | c.300G>A p.L100= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV66459730; called by muse, mutect2, varscan2
- USP9X | c.1782C>T p.P594= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV61069888; called by muse, mutect2
- ZC3H4 | c.3891G>T p.T1297= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV53413431; called by muse, mutect2, varscan2
- ZHX1 | c.1566A>G p.S522= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52876782; called by muse, mutect2, varscan2
- ZNF14 | c.1440T>C p.C480= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59849897; called by mutect2, varscan2
- ZP3 | c.1152C>T p.D384= (on ENST00000394857 / NM_001110354.2; = p.D333= on NM_007155.6) | Silent (SNP) | VAF 47/392 reads (12%) | catalogued as COSV100334599; called by muse, varscan2
- H2BP2 | n.1061+545G>A | Intron (SNP) | VAF 34/602 reads (6%) | called by muse, mutect2
- PRR14L | chr22:31676925 C>A | 3'Flank (SNP) | VAF 16/97 reads (16%) | catalogued as rs763558555; called by muse, mutect2, varscan2
- PRSS3 | c.-176G>A | 5'UTR (SNP) | VAF 19/132 reads (14%) | catalogued as COSV61556426; called by muse, mutect2, varscan2
